Somatic mutation profile of tumor specimen TARGET-30-PATHVK-01A (aliquot TARGET-30-PATHVK-01A-01D) from TARGET case TARGET-30-PATHVK, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 5.8 years (2,109 days).
Specimen TARGET-30-PATHVK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d765d678-149c-49fa-9da0-a4b1ba222e5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATHVK-10A (Blood Derived Normal), aliquot TARGET-30-PATHVK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7faf473e-10c4-443e-b870-ce67e5c528f2

The open-access MAF lists 52 somatic variants for this specimen: 45 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 6, Nonsense Mutation 4, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.6205C>A p.L2069I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.086); catalogued as COSV70033729; called by muse, mutect2, varscan2
- ACAA1 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs1273986265, COSV57176587; called by muse, mutect2, varscan2
- ANK3 | c.11579G>C p.R3860T | Missense Mutation (SNP) | VAF 90/195 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV55066390, COSV99783225; called by muse, mutect2, varscan2
- AOC3 | c.973G>T p.V325F | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53827078; called by muse, mutect2, varscan2
- ARV1 | c.65C>A p.T22N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV59618180; called by muse, mutect2, varscan2
- ATF3 | c.305A>G p.K102R | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV58378136; called by muse, mutect2, varscan2
- ATP2A3 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758021237, COSV59231280; called by muse, mutect2, varscan2
- CCDC191 | c.1560C>A p.H520Q | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.187); catalogued as COSV55673780; called by muse, mutect2, varscan2
- CCDC71 | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV58910417; called by muse, mutect2, varscan2
- COG2 | c.1895A>C p.Q632P | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.131); catalogued as COSV64187415; called by muse, mutect2, varscan2
- CRNN | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 89/305 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55122753; called by muse, mutect2, varscan2
- CUL9 | c.4063G>T p.D1355Y | Missense Mutation (SNP) | VAF 57/246 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52730784; called by muse, varscan2
- EGF | c.2528A>G p.Y843C | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs1212404748, COSV54480924; called by muse, mutect2, varscan2
- GABRB2 | c.1330G>T p.A444S (on ENST00000274547; = p.A406S on NM_000813.3) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.217); catalogued as COSV50922254; called by muse, mutect2, varscan2
- HSF2 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 31/57 reads (54%) | catalogued as COSV63774163; called by muse, mutect2, varscan2
- IL18RAP | c.164A>G p.H55R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV51827193; called by muse, mutect2, varscan2
- LATS2 | c.1650G>T p.E550D | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1274023590, COSV66877199; called by muse, mutect2, varscan2
- LIX1L | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs142637090; called by muse, mutect2, varscan2
- MYH11 | c.5438A>T p.K1813M | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55559004; called by muse, mutect2, varscan2
- MYH2 | c.5518G>T p.A1840S | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV55441773, COSV99821046; called by muse, mutect2, varscan2
- MYH2 | c.490C>A p.Q164K | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV55433784; called by muse, mutect2
- NLRP4 | c.2192T>C p.V731A | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV56717108; called by muse, mutect2, varscan2
- NPAP1 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 77/266 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV61508576; called by muse, mutect2, varscan2
- OR5M11 | c.531C>G p.Y177* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV73141919; called by muse, mutect2, varscan2
- PFKL | c.716G>T p.W239L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62464134; called by muse, mutect2, varscan2
- PGGHG | c.1161C>G p.D387E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67141141; called by muse, mutect2, varscan2
- PLEKHG7 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.387); catalogued as rs900166826, COSV60822128; called by muse, mutect2, varscan2
- PRAME | c.289T>G p.F97V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV67161945; called by muse, mutect2, varscan2
- PRSS58 | c.698G>T p.W233L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73488743; called by muse, mutect2, varscan2
- RAG1 | c.240G>T p.L80F | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100201104, COSV55026247; called by muse, mutect2, varscan2
- RAPGEF2 | c.3323C>G p.S1108* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV52430324; called by muse, mutect2, varscan2
- RFX4 | c.1846C>A p.P616T (on ENST00000392842 / NM_213594.3; = p.P522T on NM_032491.6) | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as COSV57577483, COSV57580234; called by muse, varscan2
- RNF17 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs770376749, COSV55044158; called by muse, mutect2, varscan2
- ROCK2 | c.769A>C p.I257L | Missense Mutation (SNP) | VAF 68/311 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55081054; called by muse, mutect2, varscan2
- SCAMP3 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767572161, COSV56946241; called by muse, mutect2, varscan2
- SELENOV | c.997C>A p.Q333K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.071); catalogued as COSV59064220; called by muse, mutect2, varscan2
- SLC9A2 | c.575G>T p.C192F | Missense Mutation (SNP) | VAF 74/271 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV52133896; called by muse, mutect2, varscan2
- TNS2 | c.2549C>T p.T850M (on ENST00000314250 / NM_170754.4; = p.T860M on NM_015319.2) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs550681853, COSV56854700; called by muse, mutect2, varscan2
- TTN | c.81325G>T p.E27109* (on ENST00000591111; = p.E19685* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 30/99 reads (30%) | catalogued as COSV60167942, COSV60168101; called by muse, mutect2, varscan2
- TTN | c.59993G>A p.R19998Q (on ENST00000591111; = p.R12574Q on NM_003319.4) | Missense Mutation (SNP) | VAF 66/253 reads (26%) | PolyPhen probably damaging (0.996); catalogued as rs373282633, COSV60180849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBR5 | c.3095C>G p.A1032G | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.057); catalogued as rs775851259, COSV55292250; called by muse, mutect2, varscan2
- USP15 | c.2371T>A p.C791S (on ENST00000280377 / NM_001351159.2; = p.C762S on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54794814; called by muse, mutect2, varscan2
- USP5 | c.541T>G p.F181V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV57538507; called by muse, mutect2, varscan2
- ZIC1 | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV51555479; called by muse, mutect2, varscan2
- ZSCAN5B | c.971C>A p.P324Q | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); catalogued as COSV62000544; called by muse, mutect2, varscan2
- CHMP3 | c.543C>T p.P181= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- HIPK3 | c.1962T>G p.L654= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV57563664; called by muse, mutect2, varscan2
- LRRC56 | c.249C>A p.G83= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV54243717; called by muse, varscan2
- NUP188 | c.2286T>C p.F762= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV65363246; called by muse, mutect2, varscan2
- SSU72P8 | c.450G>T p.L150= | Silent (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- TTN | c.35076C>A p.P11692= (on ENST00000591111; = p.P10765= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as rs776088323, COSV60168153; ClinVar: likely benign; called by muse, mutect2, varscan2
- C14orf177 | n.468G>T | RNA (SNP) | VAF 24/46 reads (52%) | catalogued as COSV57901239; called by muse, mutect2, varscan2
